Gene-level copy-number profile of specimen HCM-BROD-1122-C49-85B from HCMI case HCM-BROD-1122-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Tumor grade: GX; Age at diagnosis: 34.7 years (12,656 days).
Specimen HCM-BROD-1122-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2aeadfe3-be2e-425e-8b6a-f4b4536186b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1122-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/6fdc3236-f0b1-4e1c-a7e0-58df205e8b3c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 294; copy number 2: 58,002; copy number 3: 91; copy number 4: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
